Gene-level copy-number profile of tumor specimen ALCH-B1VD-TTP1-A from ALCHEMIST case ALCH-B1VD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.0 years (21,914 days).
Specimen ALCH-B1VD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a445f20e-1eb7-4870-9cdc-92b7a30ec89d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/1c9524d0-a67b-4d59-bf12-4510c9962915

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 30,637; copy number 2: 24,708; copy number 3: 3,141; copy number 4: 245; copy number 5: 41; copy number 6: 30; copy number 9: 1; copy number 11: 3; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–1): RNU6-904P, RPS16P3.
- chr3:46,668,995–46,710,886, 2 genes: ALS2CL, TMIE.
- chr3:46,719,583–46,736,429, 1 gene (within-gene range 0–2): PRSS46P.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr6:129,819,637–129,820,170, 1 gene: AL451046.1.
- chr7:1,815,793–2,242,215, 4 genes (within-gene range 0–2): MAD1L1, AC069288.1, AC104129.1, MIR4655.
- chr8:53,162,339–53,162,987, 1 gene: AC009646.1.
- chr8:142,567,260–142,577,881, 1 gene: MROH4P.
- chr9:61,190,003–61,662,690, 11 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:134,317,098–134,440,585, 2 genes: RXRA, MIR4669.
- chr9:135,663,322–135,666,422, 1 gene: LCN9.
- chr13:60,396,457–60,613,734, 2 genes: TDRD3, RNA5SP31.
- chr13:60,636,888–60,733,600, 2 genes: EIF4A1P6, AL161901.1.
- chr16:366,969–412,487, 5 genes: MRPL28, PGAP6, Z97634.1, NME4, DECR2.
- chr16:32,439,069–32,441,159, 1 gene: PABPC1P13.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:82,078,338–82,098,294, 1 gene: FASN.
- chr19:1,107,637–1,259,140, 7 genes: SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN.
- chr19:10,960,932–11,079,426, 4 genes: SMARCA4, AC011442.1, RN7SL192P, AC006127.1.
- chr19:14,566,078–15,023,276, 24 genes: NDUFB7, CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105.
- chr22:18,883,502–18,884,682, 1 gene (within-gene range 0–3): AC008103.1.
- chr22:20,058,030–20,070,965, 3 genes (within-gene range 0–1): AC006547.1, AC006547.3, Metazoa_SRP.
- chr22:41,922,032–41,926,806, 2 genes: TNFRSF13C, MIR378I.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,461 genes in 72 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–157,887, 16 genes, copy number 3: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr1:1,352,689–2,310,213, 48 genes, copy number 3: MXRA8, AURKAIP1, NDUFB4P8, CCNL2, MRPL20-AS1, MRPL20, RN7SL657P, MRPL20-DT, ANKRD65, AL391244.1, TMEM88B, LINC01770, VWA1, ATAD3C, ATAD3B, ATAD3A, TMEM240, SSU72, AL645728.1, AL691432.3, FNDC10, AL691432.2, MIB2, MMP23B, CDK11B, FO704657.1, SLC35E2B, AL691432.1, MMP23A, CDK11A, AL031282.2, AL031282.1, SLC35E2A, NADK, GNB1, AL109917.1, CALML6, TMEM52, CFAP74, AL391845.2, GABRD, AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1, FAAP20, AL590822.1, SKI.
- chr1:30,409,560–30,757,774, 7 genes, copy number 5: AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420.
- chr1:40,783,787–44,815,585, 137 genes, copy number 3–6 (broad region; genes not listed).
- chr1:93,847,174–96,823,738, 55 genes, copy number 3–4: AL049796.1, DNTTIP2, GCLM, CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4, AC093579.1, ARHGAP29, RN7SL440P, ARHGAP29-AS1, GAPDHP29, AC097059.1, AC118469.1, ABCD3, F3, AC093117.1, SLC44A3-AS1, KATNBL1P2, MIR378G, SLC44A3, CNN3, AC105942.1, ALG14, ALG14-AS1, TLCD4, TLCD4-RWDD3, AC092802.3, Y_RNA, AC092802.1, RWDD3, AC092802.2, LINC01760, LINC01650, AL445218.1, LINC01761, LINC02607, AL683887.1, LINC02790, RNU1-130P, LINC01787, AC092393.1, UBE2WP1, EEF1A1P11, RN7SL831P, NDUFS5P2, RPL7P9, RN7SKP270, PTBP2.
- chr2:60,852,260–60,938,604, 6 genes, copy number 4: RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3.
- chr2:69,829,660–74,942,670, 153 genes, copy number 3 (broad region; genes not listed).
- chr2:89,040,224–100,611,542, 272 genes, copy number 3–5 (broad region; genes not listed).
- chr3:4,490,891–4,985,323, 7 genes, copy number 3: ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40.
- chr3:151,425,384–152,151,724, 13 genes, copy number 4 (within-gene range 2–4): IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1.
- chr4:48,497,357–49,233,965, 13 genes, copy number 3: FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23.
- chr4:57,720,035–77,819,615, 297 genes, copy number 3 (broad region; genes not listed).
- chr5:179,492,076–179,806,952, 19 genes, copy number 3 (within-gene range 1–3): U4, AC136628.4, AC136628.2, AC136628.3, RUFY1, PRDX2P3, RUFY1-AS1, HNRNPH1, Metazoa_SRP, C5orf60, AC136604.1, AC136604.2, CBY3, CANX, HMGB3P22, MAML1, LTC4S, MGAT4B, MIR1229.
- chr6:60,281,444–62,611,327, 14 genes, copy number 3: AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr6:134,343,307–135,497,765, 22 genes, copy number 3: LINC01010, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA.
- chr6:157,289,025–157,945,077, 9 genes, copy number 4 (within-gene range 2–4): TMEM242, LDHAL6FP, AL390955.2, AL390955.1, AL117344.1, ZDHHC14, MIR3692, SNX9, AL391863.2.
- chr6:162,727,132–170,738,536, 137 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:32,456,963–32,762,924, 10 genes, copy number 3: AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997.
- chr7:42,661,716–51,316,818, 156 genes, copy number 3 (broad region; genes not listed).
- chr7:57,770,619–62,275,678, 14 genes, copy number 3: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr7:76,549,360–115,231,355, 632 genes, copy number 3 (broad region; genes not listed).
- chr7:149,003,062–159,233,377, 214 genes, copy number 3 (broad region; genes not listed).
- chr8:125,430,358–128,564,679, 44 genes, copy number 4: TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr9:133,328,776–133,528,612, 18 genes, copy number 4: SURF6, Y_RNA, MED22, AL772161.1, RPL7A, SNORD24, SNORD36B, SNORD36A, SNORD36C, SURF1, SURF2, SURF4, STKLD1, REXO4, ADAMTS13, CACFD1, SLC2A6, MYMK.
- chr10:73,674,295–75,431,588, 59 genes, copy number 3 (within-gene range 2–3): BMS1P4-AGAP5, BMS1P4, AC022400.4, RNA5SP320, BMS1P4, GLUD1P3, DUSP8P5, AC022400.3, AC022400.6, SEC24C, AC022400.7, FUT11, CHCHD1, ZSWIM8, AC022400.8, ZSWIM8-AS1, AC022400.5, NDST2, CAMK2G, AC022400.1, AC022400.2, PLAU, C10orf55, VCL, AL596247.1, AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr11:97,000,274–98,945,079, 10 genes, copy number 3: MED28P5, AP001836.1, LINC02553, RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1.
- chr12:17,479,446–19,376,400, 18 genes, copy number 3: AC048352.1, LINC02378, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P.
- chr12:61,231,159–62,935,150, 23 genes, copy number 3 (within-gene range 1–3): AC090017.1, DUX4L52, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P.
- chr13:54,938,604–58,209,483, 21 genes, copy number 3: AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, SPATA2P1, RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1, RNA5SP30, LINC02338.
- chr15:81,427,448–100,651,701, 444 genes, copy number 3 (broad region; genes not listed).
- chr16:32,454,612–32,678,831, 10 genes, copy number 3–13: AC138915.3, AC138915.1, ABCD1P3, AC137800.1, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr17:30,906,344–30,999,911, 9 genes, copy number 4 (within-gene range 2–4): ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7.
- chr17:35,400,878–38,257,192, 128 genes, copy number 3–4 (broad region; genes not listed).
- chr17:42,270,517–46,028,334, 224 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr17:59,674,636–59,892,945, 7 genes, copy number 3 (within-gene range 2–3): PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2.
- chr18:14,153,001–15,330,282, 42 genes, copy number 3: NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005901.2, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr18:21,242,242–21,893,996, 21 genes, copy number 5: GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P.
- chr19:1,392,170–1,479,219, 8 genes, copy number 3 (within-gene range 1–3): AC005329.1, GAMT, DAZAP1, RPS15, AC027307.3, APC2, AC027307.2, C19orf25.
- chr19:16,412,684–16,690,023, 23 genes, copy number 3: AC020917.1, AC020917.2, CALR3, AC008764.1, C19orf44, CHERP, RN7SL146P, AC008764.6, SLC35E1, AC008764.3, AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A.
- chr20:19,212,642–20,854,642, 22 genes, copy number 4–6: SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1.

Autosomal genes at a single copy (total copy number 1): 27,800. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
